Gene-level copy-number profile of tumor specimen HCM-CSHL-0080-C25-01A from HCMI case HCM-CSHL-0080-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.9 years (22,238 days).
Specimen HCM-CSHL-0080-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d32ceb15-7a0e-49b0-a8a8-3805a1a38501.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0080-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/94b9a387-7540-4d04-91bd-d4f4e24f40ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,366; copy number 2: 50,563; copy number 3: 3,649; copy number 4: 760; copy number 5: 23; copy number 6: 11; copy number 19: 8; copy number 35: 14.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:34,329,506–34,397,810, 4 genes: NUDT2, MYORG, C9orf24, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,121,786–90,154,574, 2 genes, copy number 5 (within-gene range 5–7): IGKV2D-14, IGKV1D-13.
- chr2:90,172,802–90,173,414, 1 gene, copy number 5: IGKV3D-11.
- chr8:127,072,694–128,220,803, 22 genes, copy number 19–35: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr15:38,628,005–39,180,499, 1 gene, copy number 5 (within-gene range 2–5): LINC02694.
- chr15:38,851,306–39,427,195, 4 genes, copy number 5 (within-gene range 3–5): AC022929.2, AC013652.1, AC087878.1, AC113146.1.
- chr15:83,447,228–83,618,743, 1 gene, copy number 6: SH3GL3.

Autosomal genes at a single copy (total copy number 1): 2,608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
